Gene-level copy-number profile of tumor specimen TCGA-FD-A6TE-01A from TCGA case TCGA-FD-A6TE, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 54.4 years (19,874 days).
Specimen TCGA-FD-A6TE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.c78fa3bb-f2bf-4bf7-a568-940c540d5fba.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A6TE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cffb7512-76c5-4617-988d-957ee6d58c29

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 2: 14,995; copy number 3: 14,358; copy number 4: 24,207; copy number 5: 2,218; copy number 6: 3,143; copy number 7: 314; copy number 8: 212; copy number 9: 117; copy number 10: 208.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A6TE-01A-12D-A338-01): tumor purity 0.82, ploidy 3.46, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:73,253,759–73,358,859, 1 gene (within-gene range 0–2): CFAP70.
- chr10:73,346,936–73,433,561, 5 genes: Y_RNA, ANXA7, AL512656.1, RPL26P6, MSS51.
- chr10:87,994,618–89,556,641, 37 genes: AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H, LIPA, IFIT2, AL353751.1, IFIT3, IFIT6P, IFIT1B, IFIT1, IFIT5, SLC16A12, SLC16A12-AS1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 325 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,775,954–164,357,364, 109 genes, copy number 10 (broad region; genes not listed).
- chr5:6,839,460–7,219,291, 1 gene, copy number 9 (within-gene range 8–9): LINC02196.
- chr5:7,047,227–13,944,543, 116 genes, copy number 9 (broad region; genes not listed).
- chr10:73,495,525–75,431,588, 69 genes, copy number 10 (within-gene range 2–10) (broad region; genes not listed).
- chr10:75,450,081–75,552,553, 2 genes, copy number 10: AC010997.6, MIR606.
- chr10:76,869,601–78,675,109, 28 genes, copy number 10 (within-gene range 6–10): KCNMA1, KCNMA1-AS1, KCNMA1-AS2, AL731575.1, KCNMA1-AS3, COX6CP15, RNA5SP321, AL731556.1, AL731556.2, RNU6-1266P, IMPDH1P5, AL450306.1, DLG5, AL391421.1, RN7SL284P, DLG5-AS1, H2AZP5, Metazoa_SRP, POLR3A, RPS24, GNAI2P2, AL731555.1, AC012560.1, LINC00595, AC010163.3, AC010163.1, AC010163.2, SNORA71.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
